Somatic mutation profile of tumor specimen TCGA-DE-A0Y3-01B (aliquot TCGA-DE-A0Y3-01B-11D-A10S-08) from TCGA case TCGA-DE-A0Y3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage IVC; Age at diagnosis: 60.9 years (22,239 days).
Specimen TCGA-DE-A0Y3-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a9bb915b-0bf1-4824-9642-4dc411652d15.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A0Y3-10A (Blood Derived Normal), aliquot TCGA-DE-A0Y3-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ae39ed33-5bc6-476a-9a61-4918ab1f82ea

The open-access MAF lists 15 somatic variants for this specimen: 9 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 7, Silent 6, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 63/145 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- FANK1 | c.10C>T p.Q4* | Nonsense Mutation (SNP) | VAF 4/14 reads (29%) | hotspot (GDC flag); catalogued as rs202109621, COSV64160606; called by muse, mutect2
- MAGI2 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 47/108 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV62704225; called by muse, mutect2, varscan2
- PDK3 | c.37C>T p.P13S | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV64794676; called by muse, mutect2, varscan2
- PIK3C2G | c.1555C>T p.P519S | Missense Mutation (SNP) | VAF 42/101 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.115); catalogued as rs1403002974, COSV56837749; called by muse, mutect2, varscan2
- SLC6A18 | c.202G>A p.G68R | Missense Mutation (SNP) | VAF 25/43 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57254971; called by muse, mutect2, varscan2
- ZSCAN5A | c.43T>A p.C15S | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.9); PolyPhen benign (0.115); catalogued as COSV54232570; called by muse, mutect2
- CCL23 | c.332G>A p.C111Y | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MTX1 | c.98_101del p.Q33Pfs*84 | Frame Shift Del (DEL) | VAF 11/40 reads (28%) | called by mutect2, pindel, varscan2
- ADAM21 | c.642T>A p.V214= | Silent (SNP) | VAF 83/171 reads (49%) | catalogued as COSV50814183; called by muse, mutect2, varscan2
- BATF | c.181C>T p.L61= | Silent (SNP) | VAF 8/86 reads (9%) | catalogued as COSV54377255; called by muse, mutect2
- FNIP1 | c.1971A>G p.E657= | Silent (SNP) | VAF 11/368 reads (3%) | catalogued as COSV57201533; called by muse, mutect2
- MATR3 | c.30C>T p.L10= | Silent (SNP) | VAF 8/234 reads (3%) | catalogued as COSV63080633; called by muse, mutect2
- NOP53 | c.570G>A p.R190= | Silent (SNP) | VAF 14/32 reads (44%) | catalogued as COSV55882186; called by muse, mutect2, varscan2
- PLCE1 | c.5682C>T p.V1894= | Silent (SNP) | VAF 31/230 reads (13%) | catalogued as COSV53339537; called by muse, mutect2, varscan2
